Somatic mutation profile of tumor specimen MP2PRT-PAPTJW-TMP1-A (aliquot MP2PRT-PAPTJW-TMP1-A-1-0-D-A83N-36) from MP2PRT case MP2PRT-PAPTJW, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.3 years (1,216 days).
Specimen MP2PRT-PAPTJW-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2574ef8c-58db-4930-87ad-3d4472b02eae.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAPTJW-NM1-A (Blood Derived Cancer - Bone Marrow, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAPTJW-NM1-A-1-0-D-A83N-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/19b3527a-8f2c-4ee2-a754-4e1f22474a05

The open-access MAF lists 15 somatic variants for this specimen: 11 protein-altering or splice-affecting, 4 silent.
By variant classification: Missense Mutation 10, Silent 4, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADAMTS10 | c.3125C>T p.T1042M | Missense Mutation (SNP) | VAF 28/564 reads (5%) | SIFT tolerated (0.21); PolyPhen benign (0.044); catalogued as rs1555736444, COSV54351908; called by muse, mutect2
- ANAPC2 | c.928G>A p.A310T | Missense Mutation (SNP) | VAF 142/398 reads (36%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as rs779501231, COSV59244193; called by muse, varscan2
- RNF133 | c.319C>T p.R107W | Missense Mutation (SNP) | VAF 112/290 reads (39%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.871); catalogued as rs201255578, COSV57368893; called by muse, mutect2, varscan2
- SNRNP200 | c.3269G>A p.R1090Q | Missense Mutation (SNP) | VAF 32/304 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs397514574, CM100404; called by muse, mutect2, varscan2
- SSH1 | c.2096G>A p.R699H | Missense Mutation (SNP) | VAF 61/424 reads (14%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.379); catalogued as rs751926975; called by muse, mutect2, varscan2
- CENPVL3 | c.623C>T p.T208M | Missense Mutation (SNP) | VAF 52/354 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- DPM1 | c.399-36_409del p.X133_splice | Splice Site (DEL) | VAF 63/248 reads (25%) | called by mutect2, pindel
- PAIP2 | c.361G>C p.G121R | Missense Mutation (SNP) | VAF 10/316 reads (3%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); called by muse, mutect2
- PPIG | c.1766A>T p.E589V | Missense Mutation (SNP) | VAF 60/484 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.367); called by muse, mutect2, varscan2
- SOGA3 | c.2003A>G p.E668G | Missense Mutation (SNP) | VAF 158/426 reads (37%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.867); called by muse, mutect2, varscan2
- ZEB2 | c.3215A>G p.Q1072R | Missense Mutation (SNP) | VAF 94/395 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); called by muse, mutect2, varscan2
- CRP | c.585C>T p.G195= | Silent (SNP) | VAF 30/368 reads (8%) | catalogued as rs750660593, COSV54813954; called by muse, mutect2
- ERBB4 | c.867T>C p.C289= | Silent (SNP) | VAF 104/289 reads (36%) | called by muse, mutect2, varscan2
- HS2ST1 | c.657G>A p.P219= | Silent (SNP) | VAF 85/265 reads (32%) | catalogued as rs752107517; called by muse, mutect2, varscan2
- MYBPC2 | c.2541C>G p.R847= | Silent (SNP) | VAF 46/485 reads (9%) | called by muse, mutect2
